Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3679, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3679-01A (Primary Tumor).

Diagnosis:

Colon resection material 8 cm in length includes an extensively ulcerated, colorectal type of adenocarcinoma of almost circular growth extending 3 cm lengthwise and situated in the center of the preparation with infiltration of the pericolic fatty tissue and five regional lymph node metastases. No evidence of penetration of the overlying serosa. Tumor-free colon resection margins.

Tumor stage: pT3 pN2 (5/12) pM1 (clinical liver metastases); G2, L1, V0, locally R0).

2.: Inflammation-free small intestine or Meckel's diverticulum without evidence of tissue heterotopy.

Source: NCI Genomic Data Commons file 02146566-abfa-4a87-87f2-6c4d31476112 (TCGA-AA-3679.C425B16D-B52D-4272-BC6B-73005A14D84E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).